Surgical pathology report (de-identified scan), TCGA case TCGA-36-2548, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2548-01A (Primary Tumor).

[page 1 of 2]
TCGA-36-2548

Surgical Pathology Consultation Report

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

A. Omentum: Extensive involvement by high-grade serous carcinoma.

B. Right ovary: Extensive involvement of the ovary, fallopian tube, and surrounding soft tissues by high-grade serous carcinoma (see comment).

C. Peritoneal washings () positive for high-grade serous carcinoma.

Final Diagnosis Comment:

Both the tube and the ovary are extensively replaced by high-grade serous carcinoma and thus it is not possible to determine if the tumour arose in the ovary or the fallopian tube. The degree of ovarian involvement exceeds that allowable for ovarian involvement by a peritoneal serous carcinoma.

[page 2 of 2]
Clinical History as Provided by Submitting Physician:

Ovarian Ca

-
- A. Omentum
- B. Right ovary

Specimens Received:

A: omentum

B: right ovary

Gross Description:

The specimen is received in two containers, each labelled with the patient's name.

Container A is labelled OMENTUM. The specimen consists of an apron of great omentum measuring 18 x 10 x 2.5 cm that is distorted by numerous fibrous nodules ranging in size from 0.7 up to 5.5 cm in greatest dimension. Representative sections are submitted in A1-A4.

Container B is labelled RIGHT OVARY. The specimen consists of a nodule measuring 4 cm x 2.5 x 3 cm, with an obvious tumour mass protruding on the external surface. Cross section of the specimen shows possible residual ovarian tissue. Representative sections are submitted in B1-B6.

Source: NCI Genomic Data Commons file d400ddd7-9f14-4e79-a252-545fb28e97b1 (TCGA-36-2548.68BF291C-3320-46F9-8E5F-7DE81F0C6964.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).